Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6WQ, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6WQ-01A (Primary Tumor).

ICD-O-3
Oligoastrocytoma, grade II
9382/3
Site Brain, supratentorial, NOS
C71.0
JW 8/12/13

Untranslated full report
is housed at the BCR.

Translation

diffuse glioma with astrocytic and oligo-
dendroglial differentiation
IDH1 mutation

1p/19q loss

In conclusion, this tumor is now reclassified as
oligoastrocytoma

Diagnosis:

Oligoastrocytoma WHO grade II

Criteria	7/18/13	No

Source: NCI Genomic Data Commons file 2d93aa33-e99e-4948-bcae-180c438ee11e (TCGA-S9-A6WQ.E2BDCD9B-B785-46F6-A55C-7F6AE6456BFA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).